Somatic mutation profile of tumor specimen ALCH-B0GT-TTP1-A (aliquot ALCH-B0GT-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-B0GT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.3 years (19,477 days).
Specimen ALCH-B0GT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fa3cf1b-4f06-4214-8909-56abd2f119f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0GT-NB1-A (Blood Derived Normal), aliquot ALCH-B0GT-NB1-A-2-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32405db0-cc52-4884-8c52-d5f13dceac75

The open-access MAF lists 39 somatic variants for this specimen: 23 protein-altering or splice-affecting, 10 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 10, Nonsense Mutation 4, Intron 3, 3'Flank 2, Nonstop Mutation 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM4E | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 46/217 reads (21%) | catalogued as rs782730805; called by muse, mutect2, varscan2
- KRT85 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 68/318 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs139756703; called by muse, mutect2, varscan2
- LGALS14 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 31/266 reads (12%) | catalogued as rs772250741, COSV62372558; called by muse, mutect2, varscan2
- SMARCD1 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 33/209 reads (16%) | catalogued as COSV67412608; called by muse, mutect2, varscan2
- TOP1MT | c.1765G>T p.A589S | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.745); catalogued as COSV61319768; called by muse, mutect2
- ABCB4 | c.1322T>G p.L441R | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKFY1 | c.2716A>T p.K906* (on ENST00000341657 / NM_001330063.2; = p.K907* on NM_016376.5) | Nonsense Mutation (SNP) | VAF 11/109 reads (10%) | called by muse, mutect2, varscan2
- CARF | c.836G>A p.S279N | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CFHR4 | c.536A>C p.Y179S (on ENST00000367416 / NM_001201551.2; = p.Y180S on NM_001201550.3) | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHD6 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 24/412 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); called by muse, mutect2
- CRIM1 | c.1583A>T p.E528V | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- GLOD4 | c.20T>A p.L7Q | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GUCY1A1 | c.2071T>G p.*691Eext*15 | Nonstop Mutation (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- KCNH7 | c.372G>A p.M124I | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- KRT12 | c.1028G>A p.S343N | Missense Mutation (SNP) | VAF 78/489 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MALSU1 | c.16C>G p.R6G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); called by mutect2, varscan2
- OSBPL6 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- PLCB3 | c.2426G>A p.R809Q | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SRCAP | c.3787G>A p.V1263M | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- THOC2 | c.3302A>G p.H1101R | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- TMEM35A | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TMPRSS6 | c.2250+1G>A p.X750_splice | Splice Site (SNP) | VAF 15/370 reads (4%) | called by muse, mutect2
- ZFP37 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APEH | c.402C>T p.N134= | Silent (SNP) | VAF 61/282 reads (22%) | called by muse, mutect2, varscan2
- GALE | c.429C>T p.P143= | Silent (SNP) | VAF 38/244 reads (16%) | catalogued as COSV99354137; called by muse, mutect2, varscan2
- GAS7 | c.588C>T p.T196= (on ENST00000432992 / NM_201433.2; = p.T56= on NM_003644.3) | Silent (SNP) | VAF 18/125 reads (14%) | catalogued as rs772183594, COSV60440569; called by muse, mutect2, varscan2
- HSPA14 | c.1458A>G p.G486= | Silent (SNP) | VAF 34/182 reads (19%) | called by muse, varscan2
- ITGB8 | c.831A>G p.K277= | Silent (SNP) | VAF 34/201 reads (17%) | called by muse, mutect2, varscan2
- MYH7 | c.4206G>A p.E1402= | Silent (SNP) | VAF 10/238 reads (4%) | called by muse, mutect2
- PCDH11X | c.528C>T p.Y176= | Silent (SNP) | VAF 52/224 reads (23%) | catalogued as rs1362729829, COSV53475888; called by muse, mutect2, varscan2
- PLS3 | c.603G>A p.L201= | Silent (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- SPCS3 | c.33G>T p.L11= | Silent (SNP) | VAF 36/156 reads (23%) | called by muse, mutect2, varscan2
- WFDC9 | c.177T>C p.T59= | Silent (SNP) | VAF 19/154 reads (12%) | called by muse, mutect2, varscan2
- ABCC8 | c.1333-10C>T | Intron (SNP) | VAF 41/277 reads (15%) | called by muse, mutect2, varscan2
- COG5 | chr7:107201398 A>T | 3'Flank (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2, varscan2
- GRB10 | c.1195-39C>T | Intron (SNP) | VAF 48/297 reads (16%) | called by muse, mutect2, varscan2
- MDFIC | c.-16C>T | 5'UTR (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- MRPL37 | chr1:54220670 C>T | 3'Flank (SNP) | VAF 43/275 reads (16%) | called by muse, mutect2, varscan2
- SEC23A | c.279+53A>C | Intron (SNP) | VAF 31/127 reads (24%) | called by muse, mutect2, varscan2
